Somatic mutation profile of tumor specimen TCGA-SR-A6MX-05A (aliquot TCGA-SR-A6MX-05A-11D-A35I-08) from TCGA case TCGA-SR-A6MX, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Paraganglioma, malignant; Tissue or organ of origin: Nervous system, NOS; Age at diagnosis: 55.3 years (20,186 days).
Specimen TCGA-SR-A6MX-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 730c69ae-3907-405e-95d5-46d36739a5be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SR-A6MX-10A (Blood Derived Normal), aliquot TCGA-SR-A6MX-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17deba20-7c79-4c47-ac14-07dc6390378e

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 15, Silent 9, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRD7 | c.1222A>G p.S408G | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.356); catalogued as rs4027458; called by muse, mutect2, varscan2
- CPEB1 | c.836G>A p.G279D (on ENST00000617958; = p.G219D on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 2/20 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.124); catalogued as rs758747685; called by muse, mutect2
- FKBP9 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV54231290; called by muse, mutect2, varscan2
- PNLIPRP2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs1198140788, COSV53942794; called by muse, mutect2, varscan2
- RYR1 | c.5333C>T p.S1778L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs367543055, CM104604, COSV62104099; called by muse, mutect2, varscan2
- SLITRK1 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs757938002; called by muse, mutect2, varscan2
- ATRX | c.3175del p.E1059Nfs*59 | Frame Shift Del (DEL) | VAF 88/153 reads (58%) | called by mutect2, pindel, varscan2
- HMGCS2 | c.581G>T p.C194F | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- JMJD1C | c.3575C>G p.S1192C | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PHLPP2 | c.753C>G p.I251M | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF166 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- TGDS | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THSD1 | c.131T>C p.V44A | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TMCO3 | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- TRHDE | c.2787T>A p.N929K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USF3 | c.4366A>G p.N1456D | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BAZ2B | c.3513G>A p.V1171= | Silent (SNP) | VAF 36/60 reads (60%) | called by muse, mutect2, varscan2
- C19orf73 | c.33C>T p.G11= | Silent (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- CORO7 | c.2415G>A p.Q805= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs763232660, COSV99228061; called by muse, mutect2, varscan2
- ERAP2 | c.1389T>C p.N463= | Silent (SNP) | VAF 46/130 reads (35%) | called by muse, mutect2, varscan2
- HEMK1 | c.873C>A p.I291= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- LAMB2 | c.1698C>T p.H566= | Silent (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- PRG4 | c.3840G>A p.K1280= | Silent (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- SPINDOC | c.723C>T p.D241= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs1343788442; called by muse, mutect2, varscan2
- TJP2 | c.3138G>C p.G1046= | Silent (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
